Somatic mutation profile of tumor specimen ALCH-B2UZ-TTP1-A (aliquot ALCH-B2UZ-TTP1-A-1-0-D-A78Q-36) from ALCHEMIST case ALCH-B2UZ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 73.4 years (26,813 days).
Specimen ALCH-B2UZ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 79b21d9d-426a-46fb-9a92-7f11248fe44b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2UZ-NB1-A (Blood Derived Normal), aliquot ALCH-B2UZ-NB1-A-1-0-D-A78Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1e1d36ee-af61-46ee-a052-5b268baf86e5

The open-access MAF lists 239 somatic variants for this specimen: 165 protein-altering or splice-affecting, 45 silent, 29 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 146, Silent 45, Intron 12, Nonsense Mutation 10, RNA 9, 5'UTR 6, Splice Region 4, Splice Site 4, Translation Start Site 1, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.5653G>T p.E1885* | Nonsense Mutation (SNP) | VAF 26/532 reads (5%) | catalogued as CM003393; called by muse, mutect2
- AC078880.2 | n.162+1G>A | Splice Site (SNP) | VAF 17/572 reads (3%) | catalogued as rs1024710371; called by muse, mutect2
- ARHGEF12 | c.2733T>A p.F911L | Missense Mutation (SNP) | VAF 8/203 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV63102713; called by muse, mutect2
- ATRN | c.2069A>G p.K690R | Missense Mutation (SNP) | VAF 24/402 reads (6%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs1402988720; called by muse, mutect2
- C6 | c.95G>T p.W32L | Missense Mutation (SNP) | VAF 27/440 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54710629; called by muse, mutect2
- CACNA2D1 | c.875C>A p.A292D | Missense Mutation (SNP) | VAF 27/341 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV62384240; called by muse, mutect2
- CIDEA | c.359C>T p.P120L | Missense Mutation (SNP) | VAF 6/137 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as rs143077786; called by muse, mutect2
- CNTLN | c.2634G>T p.Q878H | Missense Mutation (SNP) | VAF 28/273 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs773972748; called by muse, mutect2, varscan2
- CNTNAP2 | c.1817G>T p.G606V | Missense Mutation (SNP) | VAF 22/579 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62252211; called by muse, mutect2
- FAM135B | c.4025A>G p.Y1342C | Missense Mutation (SNP) | VAF 10/231 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1393490526; called by muse, mutect2
- FAM135B | c.3714C>A p.N1238K | Missense Mutation (SNP) | VAF 28/506 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.272); catalogued as COSV52735523; called by muse, mutect2
- FSIP2 | c.3130G>C p.E1044Q | Missense Mutation (SNP) | VAF 12/202 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.276); catalogued as rs1300935422; called by muse, mutect2
- GRIA3 | c.2623C>A p.Q875K | Missense Mutation (SNP) | VAF 25/330 reads (8%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.761); catalogued as COSV52051544; called by muse, mutect2
- HAO1 | c.367C>T p.P123S | Missense Mutation (SNP) | VAF 12/371 reads (3%) | SIFT tolerated (0.05); PolyPhen benign (0.077); catalogued as rs1425524871; called by muse, mutect2
- HAS2 | c.1619G>T p.R540L | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.519); catalogued as COSV100392006; called by muse, mutect2
- IFI35 | c.758T>G p.I253S (on ENST00000415816 / NM_001330230.2; = p.I255S on NM_005533.5) | Missense Mutation (SNP) | VAF 12/153 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV99887723; called by muse, mutect2
- KRAS | c.203G>T p.R68M | Missense Mutation (SNP) | VAF 35/294 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55867748, COSV56172241, COSV99773308; called by muse, mutect2, varscan2
- LCE1D | c.322C>A p.Q108K | Missense Mutation (SNP) | VAF 6/29 reads (21%) | PolyPhen benign (0.201); catalogued as COSV100405917; called by muse, mutect2, varscan2
- LRRTM1 | c.1096G>T p.G366W | Missense Mutation (SNP) | VAF 6/148 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.283); catalogued as COSV99703306; called by muse, mutect2
- MGAM | c.839G>A p.W280* | Nonsense Mutation (SNP) | VAF 9/180 reads (5%) | catalogued as COSV71885385; called by muse, mutect2
- MYBPC1 | c.1957G>A p.G653R (on ENST00000550270 / NM_206820.2; = p.G678R on NM_002465.4) | Missense Mutation (SNP) | VAF 12/275 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1487491561, COSV62251021; called by muse, mutect2
- MYL10 | c.659C>T p.T220I | Missense Mutation (SNP) | VAF 27/305 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1013529491; called by muse, mutect2
- NAV3 | c.2104A>T p.S702C | Missense Mutation (SNP) | VAF 23/411 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs1432065954; called by muse, mutect2
- NLRP8 | c.1181G>T p.R394L | Missense Mutation (SNP) | VAF 25/251 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.051); catalogued as rs534456601, COSV52584441; called by muse, mutect2
- NPY2R | c.67G>T p.G23W | Missense Mutation (SNP) | VAF 9/232 reads (4%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV61527228, COSV61528234; called by muse, mutect2
- OR10J1 | c.363C>A p.D121E | Missense Mutation (SNP) | VAF 22/412 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as rs1479112189, COSV71128477; called by muse, mutect2
- OR11A1 | c.805C>T p.Q269* | Nonsense Mutation (SNP) | VAF 15/237 reads (6%) | catalogued as rs1173298903, COSV101010693; called by muse, mutect2
- OR6K3 | c.881C>A p.T294N (on ENST00000368146; = p.T278N on NM_001005327.2) | Missense Mutation (SNP) | VAF 33/361 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as rs747598192; called by muse, mutect2
- OR8K1 | c.543C>A p.S181R | Missense Mutation (SNP) | VAF 16/367 reads (4%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.02); catalogued as rs748269286, COSV54401212, COSV54405024; called by muse, mutect2
- OR8K3 | c.486G>T p.K162N | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.098); catalogued as COSV57130906; called by muse, mutect2
- OR9I1 | c.872G>T p.S291I | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as COSV56925187; called by muse, mutect2
- PCDH11X | c.3464C>T p.P1155L | Missense Mutation (SNP) | VAF 45/919 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1380329512, COSV53458739; called by muse, mutect2
- PDHA2 | c.446G>T p.G149V | Missense Mutation (SNP) | VAF 11/310 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54781156; called by muse, mutect2
- POU4F3 | c.120+5G>T | Splice Region (SNP) | VAF 35/510 reads (7%) | catalogued as rs1345364956; called by muse, mutect2
- PRKCE | c.398G>T p.G133V | Missense Mutation (SNP) | VAF 12/313 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.374); catalogued as COSV60328421; called by muse, mutect2
- PRKCG | c.822-1G>A p.X274_splice | Splice Site (SNP) | VAF 35/403 reads (9%) | catalogued as rs1568755566, COSV54730811; called by muse, mutect2
- PSG1 | c.991G>C p.G331R | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (0.19); PolyPhen probably damaging (1); catalogued as rs781367687; called by muse, mutect2
- RGSL1 | c.883C>A p.L295M | Missense Mutation (SNP) | VAF 25/245 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.726); catalogued as COSV54260165; called by muse, mutect2, varscan2
- RIMBP2 | c.1666A>T p.S556C | Missense Mutation (SNP) | VAF 14/314 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.238); catalogued as COSV99074718; called by muse, mutect2
- RTF2 | c.707G>A p.R236K | Missense Mutation (SNP) | VAF 24/448 reads (5%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV99196467; called by muse, mutect2
- SFXN2 | c.290C>G p.P97R | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64011852; called by muse, mutect2, varscan2
- SH2D4B | c.538C>A p.R180S | Missense Mutation (SNP) | VAF 17/275 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); catalogued as COSV100213419; called by muse, mutect2
- SLC8A3 | c.850G>T p.G284C | Missense Mutation (SNP) | VAF 13/336 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV63526930; called by muse, mutect2
- SPARC | c.400G>A p.G134S | Missense Mutation (SNP) | VAF 11/260 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as rs1298223581; called by muse, mutect2
- SRC | c.850G>C p.V284L | Missense Mutation (SNP) | VAF 19/260 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.946); catalogued as COSV62440632; called by muse, mutect2
- TBC1D4 | c.2868G>T p.L956F | Missense Mutation (SNP) | VAF 24/456 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100884584; called by muse, mutect2
- TMEM132D | c.746G>T p.G249V | Missense Mutation (SNP) | VAF 32/514 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.232); catalogued as COSV70600480; called by muse, mutect2
- TRIM60 | c.908C>G p.T303R | Missense Mutation (SNP) | VAF 4/84 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV61971855; called by muse, mutect2
- TRIP6 | c.943C>T p.R315C | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs546644102, COSV52342651; called by muse, mutect2
- USP34 | c.4390G>T p.D1464Y | Missense Mutation (SNP) | VAF 9/232 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1236239237, COSV101277139; called by muse, mutect2
- XYLT1 | c.1144C>A p.R382S | Missense Mutation (SNP) | VAF 15/250 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54483550; called by muse, mutect2
- ZFHX4 | c.311G>T p.R104L | Missense Mutation (SNP) | VAF 15/450 reads (3%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as rs1403886577, COSV50644596; called by muse, mutect2
- ZNF71 | c.1177G>T p.G393W | Missense Mutation (SNP) | VAF 18/254 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); catalogued as COSV60147194; called by muse, mutect2
- ZNF835 | c.346G>T p.G116W | Missense Mutation (SNP) | VAF 15/318 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV73379484; called by muse, mutect2
- ZSCAN1 | c.179G>T p.W60L | Missense Mutation (SNP) | VAF 20/224 reads (9%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.896); catalogued as COSV56606635, COSV99991843; called by muse, mutect2
- ACO1 | c.1022G>T p.G341V | Missense Mutation (SNP) | VAF 38/285 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- AMY1B | c.991T>A p.W331R | Missense Mutation (SNP) | VAF 13/540 reads (2%) | SIFT tolerated (0.7); PolyPhen benign (0.228); called by muse, mutect2
- ASPM | c.2660T>A p.L887* | Nonsense Mutation (SNP) | VAF 13/222 reads (6%) | called by muse, mutect2
- ATP5PD | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 9/195 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.05); called by muse, mutect2
- BOC | c.1229G>T p.R410M | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.492); called by mutect2, varscan2
- CACNA1C | c.5035C>G p.L1679V | Missense Mutation (SNP) | VAF 20/278 reads (7%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.931); called by muse, mutect2
- CATSPER1 | c.142C>T p.H48Y | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.63); called by muse, mutect2
- CCDC168 | c.11876A>T p.K3959M | Missense Mutation (SNP) | VAF 9/144 reads (6%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.865); called by muse, mutect2
- CCDC174 | c.967G>T p.G323W | Missense Mutation (SNP) | VAF 12/241 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); called by muse, mutect2
- CCDC80 | c.2806G>A p.D936N | Missense Mutation (SNP) | VAF 7/146 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- CDH10 | c.62C>T p.S21F | Missense Mutation (SNP) | VAF 20/416 reads (5%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2
- CDH18 | c.1550T>A p.F517Y | Missense Mutation (SNP) | VAF 7/140 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.217); called by muse, mutect2
- CIT | c.5577G>C p.G1859= | Splice Region (SNP) | VAF 5/96 reads (5%) | called by muse, mutect2
- CLEC4C | c.396G>T p.Q132H | Missense Mutation (SNP) | VAF 16/200 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); called by muse, mutect2
- CNTNAP2 | c.1206G>T p.R402S | Missense Mutation (SNP) | VAF 20/664 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CNTNAP5 | c.230G>C p.W77S | Missense Mutation (SNP) | VAF 13/234 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- COL6A5 | c.7618C>A p.L2540M (on ENST00000312481; = p.L2536M on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/168 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.359); called by muse, mutect2
- COL6A6 | c.3627G>T p.W1209C | Missense Mutation (SNP) | VAF 9/212 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); called by muse, mutect2
- COX4I1 | c.382C>A p.P128T | Missense Mutation (SNP) | VAF 20/488 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); called by muse, mutect2
- CRACR2A | c.680C>T p.A227V | Missense Mutation (SNP) | VAF 9/236 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2
- CYP4Z1 | c.607C>A p.Q203K | Missense Mutation (SNP) | VAF 12/216 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.426); called by muse, mutect2
- DCAF12L1 | c.559C>A p.L187M | Missense Mutation (SNP) | VAF 34/338 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- DCC | c.3508G>T p.G1170C | Missense Mutation (SNP) | VAF 27/510 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2
- DLX3 | c.527G>T p.W176L | Missense Mutation (SNP) | VAF 23/475 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- DNAH9 | c.7585G>T p.G2529C | Missense Mutation (SNP) | VAF 11/130 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DYNC2H1 | c.5461G>A p.D1821N | Missense Mutation (SNP) | VAF 16/408 reads (4%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.866); called by muse, mutect2
- EEF1G | c.449C>G p.T150S | Missense Mutation (SNP) | VAF 22/536 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2
- EID3 | c.782A>T p.Y261F | Missense Mutation (SNP) | VAF 16/173 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- EIF2AK1 | c.516C>G p.I172M | Missense Mutation (SNP) | VAF 15/199 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.49); called by muse, mutect2
- FBN2 | c.486C>A p.D162E | Missense Mutation (SNP) | VAF 18/507 reads (4%) | SIFT tolerated (0.84); PolyPhen probably damaging (0.967); called by muse, mutect2
- FOCAD | c.2939C>A p.S980* | Nonsense Mutation (SNP) | VAF 27/328 reads (8%) | called by muse, mutect2
- GAB4 | c.1138C>A p.Q380K | Missense Mutation (SNP) | VAF 24/318 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.012); called by muse, mutect2
- GATAD2B | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 43/599 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.017); called by muse, mutect2
- GLB1L3 | c.730G>T p.A244S | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); called by muse, mutect2
- GRID2 | c.1148G>T p.G383V | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); called by muse, mutect2
- GRM8 | c.2060C>A p.P687H | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- HACE1 | c.1337C>G p.S446C | Missense Mutation (SNP) | VAF 9/171 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); called by muse, mutect2
- HELZ2 | c.1713C>G p.I571M | Missense Mutation (SNP) | VAF 10/268 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HGFAC | c.599-1G>A p.X200_splice | Splice Site (SNP) | VAF 22/262 reads (8%) | called by muse, mutect2
- HYLS1 | c.302G>C p.R101T | Missense Mutation (SNP) | VAF 22/596 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); called by muse, mutect2
- IRS1 | c.600G>T p.E200D | Missense Mutation (SNP) | VAF 22/432 reads (5%) | SIFT tolerated (0.55); PolyPhen benign (0.017); called by muse, mutect2
- ITGB1BP1 | c.288G>A p.Q96= | Splice Region (SNP) | VAF 12/368 reads (3%) | called by muse, mutect2
- KCNJ8 | c.261C>A p.F87L | Missense Mutation (SNP) | VAF 9/220 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- KCNN3 | c.1390C>T p.L464F | Missense Mutation (SNP) | VAF 22/278 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); called by muse, mutect2
- KRTAP10-12 | c.505G>A p.A169T | Missense Mutation (SNP) | VAF 23/527 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.013); called by muse, mutect2
- KRTAP5-3 | c.106T>A p.C36S | Missense Mutation (SNP) | VAF 14/364 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.094); called by muse, mutect2
- LCE3E | c.245C>T p.S82F | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.823); called by muse, mutect2
- LHX5 | c.909G>T p.Q303H | Missense Mutation (SNP) | VAF 11/197 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.03); called by muse, mutect2
- LPO | c.1835G>T p.G612V | Missense Mutation (SNP) | VAF 23/160 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MACO1 | c.1915C>T p.H639Y | Missense Mutation (SNP) | VAF 13/232 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.824); called by muse, mutect2
- MAGEE1 | c.1310G>T p.R437M | Missense Mutation (SNP) | VAF 8/194 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.068); called by muse, mutect2
- MAP7D3 | c.1935A>T p.Q645H | Missense Mutation (SNP) | VAF 26/356 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); called by muse, mutect2
- MARCHF11 | c.591G>T p.Q197H | Missense Mutation (SNP) | VAF 20/216 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- MARK2 | c.1234+1G>T p.X412_splice | Splice Site (SNP) | VAF 9/170 reads (5%) | called by muse, mutect2
- MAT1A | c.1053G>T p.K351N | Missense Mutation (SNP) | VAF 26/688 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.007); called by muse, mutect2
- MED12L | c.3400C>A p.H1134N | Missense Mutation (SNP) | VAF 23/567 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); called by muse, mutect2
- MED17 | c.818C>T p.T273I | Missense Mutation (SNP) | VAF 25/471 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.056); called by muse, mutect2
- METTL16 | c.1504G>A p.E502K | Missense Mutation (SNP) | VAF 16/218 reads (7%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.033); called by muse, mutect2
- MMP17 | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- MPO | c.1570C>A p.R524S | Missense Mutation (SNP) | VAF 18/276 reads (7%) | SIFT tolerated (0.98); PolyPhen benign (0.353); called by muse, mutect2
- MS4A14 | c.1728C>A p.Y576* | Nonsense Mutation (SNP) | VAF 31/465 reads (7%) | called by muse, mutect2
- MUC12 | c.2182G>T p.G728C (on ENST00000379442; = p.G585C on NM_001164462.1) | Missense Mutation (SNP) | VAF 57/1356 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- MUC12 | c.2225C>G p.S742* (on ENST00000379442; = p.S599* on NM_001164462.1) | Nonsense Mutation (SNP) | VAF 40/1406 reads (3%) | called by muse, mutect2
- MUC17 | c.2780C>G p.T927R | Missense Mutation (SNP) | VAF 19/301 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.351); called by muse, mutect2
- NAP1L3 | c.842A>G p.H281R | Missense Mutation (SNP) | VAF 12/262 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.029); called by muse, mutect2
- NAV3 | c.215G>T p.G72V | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.5); called by muse, mutect2
- NLGN1 | c.2368G>T p.G790W | Missense Mutation (SNP) | VAF 16/399 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NLRP3 | c.2719A>T p.S907C | Missense Mutation (SNP) | VAF 16/460 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); called by muse, mutect2
- NMUR2 | c.1081C>A p.Q361K | Missense Mutation (SNP) | VAF 22/608 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.107); called by muse, mutect2
- NOL8 | c.1755G>T p.M585I | Missense Mutation (SNP) | VAF 16/306 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2
- NR4A2 | c.114G>T p.E38D | Missense Mutation (SNP) | VAF 22/653 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2
- OR13H1 | c.568G>A p.D190N | Missense Mutation (SNP) | VAF 7/146 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.186); called by muse, mutect2
- OR9G4 | c.695C>T p.S232L | Missense Mutation (SNP) | VAF 12/336 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.282); called by muse, mutect2
- PCDHB12 | c.764G>T p.S255I | Missense Mutation (SNP) | VAF 9/251 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.783); called by muse, mutect2
- PEX26 | c.907A>T p.I303F | Missense Mutation (SNP) | VAF 11/210 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.276); called by muse, mutect2
- PHACTR4 | c.373G>A p.E125K (on ENST00000373839 / NM_001350159.2; = p.E135K on NM_023923.4) | Missense Mutation (SNP) | VAF 12/252 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.551); called by muse, mutect2
- PIP5K1A | c.964G>C p.D322H (on ENST00000368888 / NM_001135638.2; = p.D309H on NM_003557.3) | Missense Mutation (SNP) | VAF 9/205 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2
- PLXNB2 | c.4291C>T p.Q1431* | Nonsense Mutation (SNP) | VAF 9/206 reads (4%) | called by muse, mutect2
- POFUT2 | c.793G>T p.D265Y | Missense Mutation (SNP) | VAF 8/182 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- POT1 | c.1774C>A p.P592T | Missense Mutation (SNP) | VAF 7/151 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PPP1R16A | c.769A>T p.S257C | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); called by muse, mutect2
- RALYL | c.238A>T p.I80F | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.213); called by muse, mutect2
- RNF145 | c.3G>T p.M1? (on ENST00000424310 / NM_001199383.2; = p.M29I on NM_144726.2) | Translation Start Site (SNP) | VAF 13/432 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); called by muse, mutect2
- SDK1 | c.3920G>T p.G1307V | Missense Mutation (SNP) | VAF 16/227 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SEC14L6 | c.234G>A p.E78= | Splice Region (SNP) | VAF 11/147 reads (7%) | called by muse, mutect2
- SEC23B | c.1297C>G p.P433A | Missense Mutation (SNP) | VAF 19/526 reads (4%) | SIFT tolerated (0.5); PolyPhen benign (0.007); called by muse, mutect2
- SERPINA10 | c.550A>T p.R184W | Missense Mutation (SNP) | VAF 24/625 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); called by muse, mutect2
- SH3YL1 | c.262C>T p.L88F | Missense Mutation (SNP) | VAF 12/312 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.035); called by muse, mutect2
- SLC26A8 | c.2824C>G p.Q942E | Missense Mutation (SNP) | VAF 11/310 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.054); called by muse, mutect2
- SLIT2 | c.3416G>A p.R1139K | Missense Mutation (SNP) | VAF 30/486 reads (6%) | SIFT tolerated (0.93); PolyPhen benign (0); called by muse, mutect2
- SMG1 | c.4627C>A p.L1543M | Missense Mutation (SNP) | VAF 12/345 reads (3%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.543); called by muse, mutect2
- SNAP29 | c.533G>A p.R178K | Missense Mutation (SNP) | VAF 19/484 reads (4%) | SIFT tolerated (0.92); PolyPhen benign (0); called by muse, mutect2
- SPINK5 | c.2395G>T p.D799Y | Missense Mutation (SNP) | VAF 13/265 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); called by muse, mutect2
- STOML1 | c.908C>G p.S303C | Missense Mutation (SNP) | VAF 14/401 reads (3%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.964); called by muse, mutect2
- SYVN1 | c.475G>T p.A159S | Missense Mutation (SNP) | VAF 14/376 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2
- TAFA2 | c.219G>T p.Q73H | Missense Mutation (SNP) | VAF 12/341 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TCTN3 | c.655C>T p.P219S | Missense Mutation (SNP) | VAF 16/293 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.062); called by muse, mutect2
- TMEM67 | c.1877A>T p.H626L | Missense Mutation (SNP) | VAF 39/496 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.405); called by muse, mutect2
- TNRC6C | c.4511G>T p.W1504L | Missense Mutation (SNP) | VAF 18/247 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TRIM64C | c.237G>T p.Q79H | Missense Mutation (SNP) | VAF 22/698 reads (3%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.883); called by muse, mutect2
- TSPAN12 | c.820C>T p.P274S | Missense Mutation (SNP) | VAF 18/427 reads (4%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2
- TTN | c.54179G>A p.W18060* (on ENST00000591111; = p.W10636* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 14/338 reads (4%) | called by muse, mutect2
- USH2A | c.3939T>A p.N1313K | Missense Mutation (SNP) | VAF 12/353 reads (3%) | SIFT tolerated (0.19); PolyPhen benign (0.339); called by muse, mutect2
- VWA8 | c.956C>T p.A319V | Missense Mutation (SNP) | VAF 14/252 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.007); called by muse, mutect2
- WDR11 | c.1622G>T p.G541V | Missense Mutation (SNP) | VAF 12/208 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF208 | c.1672T>C p.C558R | Missense Mutation (SNP) | VAF 19/477 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); called by muse, mutect2
- ZNF320 | c.661G>T p.E221* | Nonsense Mutation (SNP) | VAF 15/219 reads (7%) | called by muse, mutect2
- ZNF554 | c.1280A>C p.K427T | Missense Mutation (SNP) | VAF 38/490 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.053); called by muse, mutect2
- ZNF592 | c.337A>T p.T113S | Missense Mutation (SNP) | VAF 12/375 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2
- ZNF99 | c.703G>T p.G235C | Missense Mutation (SNP) | VAF 10/258 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ABCB9 | c.1686G>A p.R562= (on ENST00000280560 / NM_019625.4; = p.R519= on NM_019624.3) | Silent (SNP) | VAF 14/250 reads (6%) | called by muse, mutect2
- ACVR2B | c.114G>A p.L38= | Silent (SNP) | VAF 15/404 reads (4%) | called by muse, mutect2
- ADAMTS20 | c.99G>T p.L33= | Silent (SNP) | VAF 7/59 reads (12%) | called by muse, varscan2
- AKR1B1 | c.861C>T p.T287= | Silent (SNP) | VAF 82/888 reads (9%) | called by muse, mutect2
- ALS2CL | c.1119G>C p.L373= | Silent (SNP) | VAF 8/192 reads (4%) | called by muse, mutect2
- ARHGAP36 | c.451C>A p.R151= | Silent (SNP) | VAF 28/530 reads (5%) | catalogued as COSV52271626; called by muse, mutect2
- ARX | c.621G>T p.V207= | Silent (SNP) | VAF 6/84 reads (7%) | called by muse, mutect2
- CFAP46 | c.6957C>A p.V2319= | Silent (SNP) | VAF 5/72 reads (7%) | called by muse, mutect2
- CHCHD3 | c.283A>C p.R95= | Silent (SNP) | VAF 11/306 reads (4%) | called by muse, mutect2
- CHRNB2 | c.1014C>T p.V338= | Silent (SNP) | VAF 29/313 reads (9%) | called by muse, mutect2
- CWF19L2 | c.61C>A p.R21= | Silent (SNP) | VAF 28/361 reads (8%) | called by muse, mutect2
- FAM187B | c.1006C>T p.L336= | Silent (SNP) | VAF 13/183 reads (7%) | called by muse, mutect2
- FTMT | c.561C>A p.P187= | Silent (SNP) | VAF 15/403 reads (4%) | catalogued as COSV100360416; called by muse, mutect2
- GABRA1 | c.663T>A p.L221= | Silent (SNP) | VAF 22/484 reads (5%) | called by muse, mutect2
- GIMAP8 | c.1248G>A p.L416= | Silent (SNP) | VAF 13/138 reads (9%) | called by muse, mutect2
- GRM8 | c.609C>A p.A203= | Silent (SNP) | VAF 48/750 reads (6%) | catalogued as COSV58841165; called by muse, mutect2
- HIGD1B | c.66G>C p.L22= | Silent (SNP) | VAF 10/227 reads (4%) | called by muse, mutect2
- HK2 | c.1212G>A p.E404= | Silent (SNP) | VAF 10/345 reads (3%) | called by muse, mutect2
- IL12RB2 | c.966T>A p.T322= | Silent (SNP) | VAF 17/419 reads (4%) | called by muse, mutect2
- IRX1 | c.390G>T p.R130= | Silent (SNP) | VAF 20/306 reads (7%) | called by muse, mutect2
- KANSL3 | c.2391G>T p.T797= (on ENST00000666923 / NM_001349262.2; = p.T771= on NM_001115016.3) | Silent (SNP) | VAF 9/173 reads (5%) | called by muse, mutect2
- KCND2 | c.1176G>A p.L392= | Silent (SNP) | VAF 37/566 reads (7%) | called by muse, mutect2
- KIAA1614 | c.2340C>A p.S780= | Silent (SNP) | VAF 12/152 reads (8%) | called by muse, mutect2
- MEI1 | c.1134G>C p.L378= | Silent (SNP) | VAF 8/234 reads (3%) | called by muse, mutect2
- NCAPD3 | c.2250C>T p.P750= | Silent (SNP) | VAF 12/229 reads (5%) | called by muse, mutect2
- NKAP | c.171C>A p.T57= | Silent (SNP) | VAF 6/138 reads (4%) | called by muse, mutect2
- OR10R2 | c.582C>A p.V194= | Silent (SNP) | VAF 15/253 reads (6%) | called by muse, mutect2
- OR2A14 | c.714C>T p.S238= | Silent (SNP) | VAF 51/551 reads (9%) | catalogued as rs757291875, COSV68718036; called by muse, mutect2
- OR8K1 | c.240C>A p.S80= | Silent (SNP) | VAF 16/274 reads (6%) | catalogued as COSV54402886; called by muse, mutect2
- OR9G4 | c.696A>T p.S232= | Silent (SNP) | VAF 12/332 reads (4%) | catalogued as COSV100265306; called by muse, mutect2
- PALM2AKAP2 | c.231C>T p.F77= (on ENST00000374531 / NM_001037293.2; = p.F75= on NM_007203.5) | Silent (SNP) | VAF 10/282 reads (4%) | catalogued as rs1484607166; called by muse, mutect2
- PLXNA4 | c.5043C>T p.L1681= | Silent (SNP) | VAF 21/441 reads (5%) | called by muse, mutect2
- PSG9 | c.771C>G p.V257= | Silent (SNP) | VAF 21/379 reads (6%) | catalogued as rs772795774; called by muse, mutect2
- PYGM | c.1599G>T p.R533= | Silent (SNP) | VAF 21/502 reads (4%) | called by muse, mutect2
- ROR2 | c.1473C>T p.H491= | Silent (SNP) | VAF 14/246 reads (6%) | called by muse, mutect2
- SERINC4 | c.1476C>T p.P492= | Silent (SNP) | VAF 10/223 reads (4%) | catalogued as rs919669117; called by muse, mutect2
- SLC25A13 | c.1710G>T p.L570= | Silent (SNP) | VAF 40/740 reads (5%) | catalogued as rs1562774531; ClinVar: uncertain significance; called by muse, mutect2
- SLC6A18 | c.423G>T p.P141= | Silent (SNP) | VAF 14/122 reads (11%) | called by muse, mutect2
- SPTBN1 | c.3894C>T p.A1298= | Silent (SNP) | VAF 11/225 reads (5%) | called by muse, mutect2
- TENM2 | c.306C>A p.I102= | Silent (SNP) | VAF 29/480 reads (6%) | called by muse, mutect2
- THBS3 | c.213C>G p.V71= | Silent (SNP) | VAF 12/278 reads (4%) | called by muse, mutect2
- TMEM223 | c.48G>A p.L16= | Silent (SNP) | VAF 6/80 reads (8%) | called by muse, mutect2
- TRBV6-1 | c.78C>A p.T26= | Silent (SNP) | VAF 8/129 reads (6%) | called by muse, mutect2
- TRPC5 | c.522C>A p.I174= | Silent (SNP) | VAF 24/270 reads (9%) | called by muse, mutect2
- ZNF26 | c.765G>T p.G255= | Silent (SNP) | VAF 16/398 reads (4%) | called by muse, mutect2
- AC245884.12 | n.58G>A | RNA (SNP) | VAF 27/545 reads (5%) | called by muse, mutect2
- ACKR1 | c.-66C>T | 5'UTR (SNP) | VAF 14/320 reads (4%) | called by muse, mutect2
- AKAP17A | c.1153-474G>A | Intron (SNP) | VAF 7/114 reads (6%) | called by muse, mutect2
- AL353753.1 | n.363G>C | RNA (SNP) | VAF 27/159 reads (17%) | called by muse, mutect2, varscan2
- AL450442.1 | n.709C>A | RNA (SNP) | VAF 24/381 reads (6%) | called by muse, mutect2
- DENND3 | c.2844+14G>A | Intron (SNP) | VAF 6/96 reads (6%) | called by muse, mutect2
- ETV5 | c.-75+456G>T | Intron (SNP) | VAF 8/100 reads (8%) | called by muse, mutect2
- KCNC3 | chr19:50333927 G>A | 5'Flank (SNP) | VAF 12/182 reads (7%) | called by muse, mutect2
- KERA | c.*12C>A | 3'UTR (SNP) | VAF 16/208 reads (8%) | called by muse, mutect2
- LHX8 | c.995-44T>G | Intron (SNP) | VAF 20/243 reads (8%) | called by muse, mutect2
- LINC00602 | n.1192T>A | RNA (SNP) | VAF 9/121 reads (7%) | called by muse, mutect2
- MIR508 | n.67T>A | RNA (SNP) | VAF 8/190 reads (4%) | called by muse, mutect2
- NBPF22P | n.1353A>T | RNA (SNP) | VAF 20/362 reads (6%) | called by muse, mutect2
- NELL1 | c.1549+54914G>T | Intron (SNP) | VAF 14/364 reads (4%) | catalogued as COSV100121401; called by muse, mutect2
- NLRP12 | c.2073-46C>A | Intron (SNP) | VAF 29/342 reads (8%) | called by muse, mutect2
- PAX8 | c.-49A>T | 5'UTR (SNP) | VAF 10/247 reads (4%) | called by muse, mutect2
- PLPP1 | c.-13C>A | 5'UTR (SNP) | VAF 9/183 reads (5%) | called by muse, mutect2
- PLXNA4 | c.1371+4280C>A | Intron (SNP) | VAF 17/290 reads (6%) | called by muse, mutect2
- PTCD1 | c.-82C>T | 5'UTR (SNP) | VAF 12/170 reads (7%) | called by muse, mutect2
- PTENP1 | n.2034C>G | RNA (SNP) | VAF 14/200 reads (7%) | called by muse, mutect2
- PTPN23 | c.-18C>A | 5'UTR (SNP) | VAF 17/305 reads (6%) | called by muse, mutect2
- RNF170 | c.-8+149C>T | Intron (SNP) | VAF 3/16 reads (19%) | called by muse, mutect2
- RUFY4 | c.600+35T>A | Intron (SNP) | VAF 14/241 reads (6%) | called by muse, mutect2
- SNORD116-29 | n.71T>A | RNA (SNP) | VAF 16/292 reads (5%) | called by muse, mutect2
- SUN1 | c.-112G>C | 5'UTR (SNP) | VAF 8/72 reads (11%) | catalogued as rs1240577703, COSV101273069; called by muse, varscan2
- TBXAS1 | c.333+1825C>T | Intron (SNP) | VAF 8/187 reads (4%) | called by muse, mutect2
- TCAF2 | c.1615+196C>A | Intron (SNP) | VAF 16/110 reads (15%) | catalogued as rs1216188029; called by muse, mutect2, varscan2
- TRPA1 | c.1365-28G>C | Intron (SNP) | VAF 16/466 reads (3%) | called by muse, mutect2
- UBE2DNL | n.196G>A | RNA (SNP) | VAF 8/56 reads (14%) | called by muse, mutect2, varscan2
